Somatic mutation profile of tumor specimen TCGA-V5-A7RE-01A (aliquot TCGA-V5-A7RE-01A-11D-A351-09) from TCGA case TCGA-V5-A7RE, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 45.6 years (16,643 days).
Specimen TCGA-V5-A7RE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94deedc3-95f2-4196-8343-e2f84a713512.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V5-A7RE-10A (Blood Derived Normal), aliquot TCGA-V5-A7RE-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcfffa86-df56-4b3e-aea8-f755ad0f27bd

The open-access MAF lists 152 somatic variants for this specimen: 113 protein-altering or splice-affecting, 39 silent.
By variant classification: Missense Mutation 98, Silent 39, Nonsense Mutation 4, Frame Shift Del 4, Nonstop Mutation 3, Frame Shift Ins 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+2T>G p.X307_splice | Splice Site (SNP) | VAF 21/37 reads (57%) | hotspot (GDC flag); catalogued as rs1131691016, COSV52698436, COSV52737448, COSV52774697; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1817G>A p.G606E | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52206587; called by muse, mutect2, varscan2
- ARHGEF12 | c.2221C>T p.R741* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV63104313; called by muse, mutect2, varscan2
- ARID1A | c.5680C>T p.Q1894* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV61374094; called by muse, mutect2
- ASXL3 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV99036137; called by muse, mutect2, varscan2
- CCDC7 | c.3269A>C p.E1090A | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs775884099; called by muse, mutect2
- CDH23 | c.2032G>A p.V678I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs547668692; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH7 | c.505+1G>T p.X169_splice | Splice Site (SNP) | VAF 15/34 reads (44%) | catalogued as COSV59884351; called by muse, mutect2, varscan2
- COL11A2 | c.2536C>T p.R846W (on ENST00000341947 / NM_080680.3; = p.R739W on NM_080679.2) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs149071920; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV62033693; called by muse, mutect2, varscan2
- CYP4F11 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs745574412; called by muse, mutect2, varscan2
- DEFB118 | c.78del p.K26Nfs*19 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | catalogued as rs750510475, COSV53620107; called by mutect2, varscan2
- DIAPH3 | c.3143G>C p.R1048P (on ENST00000400324 / NM_001042517.2; = p.R785P on NM_030932.3) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as COSV57380428, COSV99933144; called by muse, mutect2, varscan2
- DIS3L | c.1267G>A p.E423K (on ENST00000319212 / NM_001143688.3; = p.E340K on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1367726275; called by muse, mutect2, varscan2
- EPB41L2 | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61353708; called by muse, mutect2, varscan2
- EVX1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1267877755; called by muse, mutect2, varscan2
- F2 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.281); catalogued as rs1379341234, COSV61316483; called by muse, mutect2, varscan2
- F9 | c.913T>C p.Y305H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM001680; called by muse, mutect2, varscan2
- FAT3 | c.10180G>T p.V3394F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV53102240; called by muse, mutect2, varscan2
- FLG | c.5096G>A p.R1699H | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs778016068, COSV64240153; called by muse, mutect2, varscan2
- FLT4 | c.3205G>A p.V1069I | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760077499; called by muse, mutect2, varscan2
- GAL3ST4 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as rs773063060, COSV57585440; called by muse, mutect2, varscan2
- GRIA3 | c.2642G>A p.R881K | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.815); catalogued as COSV52080124; called by muse, mutect2, varscan2
- H3C7 | c.403_404del p.R135Gfs*? | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs778901635; called by pindel, varscan2
- H4C12 | c.311G>C p.*104Sext*? | Nonstop Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV62743637, COSV62743749; called by muse, mutect2, varscan2
- HCN1 | c.2527C>T p.R843* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | catalogued as rs1046832984, COSV57504666, COSV57542388; called by muse, mutect2, varscan2
- IGSF3 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750045141, COSV59588918; called by muse, mutect2, varscan2
- IRX6 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as rs1487947840; called by muse, mutect2, varscan2
- ITPRID2 | c.1298G>A p.S433N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1388356986; called by muse, mutect2, varscan2
- KAT2A | c.1681G>A p.G561S | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs782626676, COSV52424922; called by muse, mutect2, varscan2
- KCNA5 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV52904767; called by muse, mutect2
- KCNV1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52085116; called by muse, mutect2, varscan2
- LRFN1 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV50440564; called by muse, mutect2, varscan2
- MAGEE1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.071); catalogued as rs1285274035, COSV63909125; called by muse, varscan2
- MARF1 | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs765688253, COSV60019667; called by muse, mutect2, varscan2
- MCMDC2 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs779816268, COSV58033565, COSV58036710; called by muse, mutect2, varscan2
- NEB | c.3830A>G p.D1277G | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1464286398; called by muse, mutect2
- NOS1 | c.1186A>T p.T396S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV57618178; called by muse, mutect2, varscan2
- OR10J5 | c.205T>C p.S69P | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1441515472; called by muse, mutect2, varscan2
- PCDH10 | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV52088218; called by muse, mutect2, varscan2
- PCDH17 | c.3050C>T p.P1017L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV64978313; called by mutect2, varscan2
- PDZD2 | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.523); catalogued as COSV56876784; called by muse, mutect2, varscan2
- PSME4 | c.3148G>A p.V1050I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as rs773394261; called by muse, mutect2, varscan2
- RP1 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); catalogued as COSV99606238; called by muse, mutect2, varscan2
- SCN3A | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1035773270, COSV99328738; called by muse, mutect2, varscan2
- SETD5 | c.2279C>T p.S760L | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100200609; called by muse, mutect2, varscan2
- SRRM3 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs782818176, COSV58391851; called by muse, mutect2
- SYCP1 | c.1202dup p.N401Kfs*2 | Frame Shift Ins (INS) | VAF 29/142 reads (20%) | catalogued as rs1189372077; called by mutect2, varscan2
- SYT3 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV58896386; called by muse, mutect2, varscan2
- USP30 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408864147; called by muse, mutect2, varscan2
- WASF1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1366275980; called by muse, mutect2, varscan2
- ABCA8 | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ANAPC7 | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC160 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CDH12 | c.1204A>G p.I402V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CHAT | c.2006G>T p.C669F | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, varscan2
- CLSTN2 | c.2011A>C p.T671P | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CNTN1 | c.3001A>G p.S1001G | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSNK1D | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DHX9 | c.3809A>T p.Y1270F | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJA1 | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- DUSP2 | c.754_760del p.R252Wfs*129 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- EEA1 | c.3769T>C p.W1257R | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ERCC3 | c.1349T>A p.M450K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FKBP10 | c.242C>A p.S81* | Nonsense Mutation (SNP) | VAF 89/500 reads (18%) | called by muse, mutect2, varscan2
- FKBP10 | c.887C>A p.S296Y | Missense Mutation (SNP) | VAF 85/525 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- FKBP10 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 60/316 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- FKBP10 | c.1076C>A p.P359H | Missense Mutation (SNP) | VAF 59/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- GALNT13 | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GPRC5C | c.265G>A p.D89N (on ENST00000652232; = p.D44N on NM_018653.4) | Missense Mutation (SNP) | VAF 57/332 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GSK3B | c.56A>G p.Q19R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIF1A | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HYOU1 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); called by muse, mutect2
- KCNN4 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP8 | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- MAP1B | c.4861C>T p.P1621S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MIEF2 | c.453G>C p.Q151H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); called by muse, mutect2
- MME | c.1022A>T p.E341V | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- MUC16 | c.6470C>A p.S2157Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- MYBPC3 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 101/137 reads (74%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO7A | c.3538A>G p.T1180A | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NBEA | c.2806A>G p.R936G | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NT5C3B | c.366G>C p.Q122H | Missense Mutation (SNP) | VAF 112/780 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OR5D18 | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.021); called by muse, mutect2
- OTUD4 | c.413del p.K138Rfs*18 (on ENST00000447906 / NM_001366057.1; = p.K73Rfs*18 on NM_017493.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/100 reads (31%) | called by mutect2, pindel, varscan2
- PHLPP1 | c.3706dup p.T1236Nfs*38 | Frame Shift Ins (INS) | VAF 13/27 reads (48%) | called by mutect2, pindel, varscan2
- PID1 | c.685G>T p.D229Y (on ENST00000354069 / NM_001330156.1; = p.D227Y on NM_017933.5) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PIWIL1 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PRAMEF5 | c.1430G>C p.*477Sext*24 | Nonstop Mutation (SNP) | VAF 9/42 reads (21%) | called by mutect2, varscan2
- PRAMEF6 | c.1430G>C p.*477Sext*24 | Nonstop Mutation (SNP) | VAF 30/180 reads (17%) | called by muse, mutect2, varscan2
- PREX2 | c.3920G>T p.W1307L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PROCA1 | c.296G>A p.C99Y (on ENST00000439862 / NM_001366301.1; = p.C71Y on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 149/459 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- PROCA1 | c.193G>C p.D65H (on ENST00000439862 / NM_001366301.1; = p.D37H on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/410 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, varscan2
- PXDN | c.727T>C p.C243R | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2
- RCOR3 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- REV3L | c.4610G>T p.R1537I | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SAAL1 | c.65G>C p.G22A | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.011); called by muse, varscan2
- SCEL | c.786A>C p.K262N (on ENST00000349847 / NM_144777.3; = p.K242N on NM_003843.4) | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SCN3A | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SLC16A1 | c.167G>C p.S56T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SLC26A5 | c.1454A>G p.D485G | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOX11 | c.1273A>C p.I425L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- TLR10 | c.1858G>A p.V620I | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TPX2 | c.1666A>C p.K556Q | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- TRIM49 | c.500G>T p.C167F | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); called by muse, mutect2
- TTK | c.2371G>C p.V791L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.262); called by muse, mutect2
- USP11 | c.2066G>T p.G689V (on ENST00000218348; = p.G646V on NM_001371072.1) | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- VWF | c.6219C>A p.S2073R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF423 | c.3423A>C p.E1141D (on ENST00000563137 / NM_001379286.1; = p.E1133D on NM_015069.4) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ZNF445 | c.1293G>C p.K431N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF91 | c.3238T>G p.C1080G | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZSWIM4 | c.1820C>T p.T607I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- ABCC9 | c.2610T>C p.T870= | Silent (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- AHCTF1 | c.5776C>T p.L1926= (on ENST00000366508; = p.L1900= on NM_015446.5) | Silent (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- AHSG | c.267C>T p.C89= | Silent (SNP) | VAF 34/49 reads (69%) | catalogued as rs1323381892; called by muse, mutect2, varscan2
- AKAP12 | c.225C>T p.S75= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1442588123; called by muse, mutect2, varscan2
- ASAP2 | c.744G>A p.L248= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs765171526; called by muse, mutect2, varscan2
- BCAM | c.1551C>T p.R517= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs372072867; called by muse, mutect2
- CD1B | c.180C>T p.S60= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs752855480, COSV100939324; called by muse, mutect2, varscan2
- CHRNA6 | c.843T>C p.S281= | Silent (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- CILP | c.3478A>C p.R1160= | Silent (SNP) | VAF 16/25 reads (64%) | called by muse, varscan2
- CNTNAP2 | c.3576C>T p.A1192= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs764089965, COSV62201707; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOP1B | c.3166C>T p.L1056= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs1385132394; called by muse, mutect2, varscan2
- FKBP10 | c.1074C>T p.I358= | Silent (SNP) | VAF 60/312 reads (19%) | called by muse, varscan2
- FLVCR1 | c.447G>A p.L149= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs371271294; called by muse, varscan2
- HUS1B | c.270G>A p.A90= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs1469406962, COSV100034286; called by muse, mutect2
- HYDIN | c.4704G>A p.Q1568= | Silent (SNP) | VAF 28/167 reads (17%) | called by muse, mutect2, varscan2
- IPO8 | c.2046T>C p.F682= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as rs1305838680; called by muse, mutect2, varscan2
- IRF4 | c.15C>T p.G5= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- KLHL38 | c.348C>T p.F116= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1331414130; called by mutect2, varscan2
- MKRN1 | c.696C>T p.H232= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs775269221, COSV55436065; called by muse, mutect2, varscan2
- MSR1 | c.837T>C p.G279= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- MYCL | c.582C>T p.D194= | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- NAALADL2 | c.1785C>T p.D595= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- NYAP1 | c.108C>T p.P36= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as rs766182413; called by muse, mutect2, varscan2
- OR11H4 | c.291C>G p.S97= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- OR51B4 | c.672C>T p.G224= | Silent (SNP) | VAF 47/69 reads (68%) | called by muse, mutect2, varscan2
- OR56A1 | c.147G>T p.L49= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- PCDHB7 | c.328T>C p.L110= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs539087999, COSV50758562; called by muse, mutect2, varscan2
- RASSF10 | c.955C>T p.L319= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs1437326581; called by muse, mutect2, varscan2
- RECQL | c.741C>T p.N247= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs148490073; called by muse, mutect2, varscan2
- RPIA | c.456C>T p.H152= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- SCARF1 | c.1830C>T p.S610= | Silent (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- SFMBT2 | c.1380C>T p.D460= | Silent (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- SLC12A5 | c.2064A>C p.P688= (on ENST00000454036 / NM_001134771.2; = p.P665= on NM_020708.5) | Silent (SNP) | VAF 26/38 reads (68%) | called by muse, mutect2, varscan2
- THUMPD1 | c.435C>A p.L145= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV67262974; called by muse, mutect2, varscan2
- TMEM254 | c.261C>T p.G87= | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- TPTE2 | c.348C>A p.G116= (on ENST00000400230 / NM_199254.2; = p.G79= on NM_130785.3) | Silent (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- USP45 | c.705C>T p.D235= | Silent (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- XIRP2 | c.774C>A p.V258= (on ENST00000628543; = p.V433= on NM_152381.6) | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- ZKSCAN7 | c.1290C>A p.L430= | Silent (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
